Somatic mutation profile of tumor specimen MBCProject_3632_T1_WES (aliquot MBCProject_3632_T1_WES_1) from CMI case MBCProject_3632, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 60.7 years (22,186 days).
Specimen MBCProject_3632_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 127f225d-73e2-4322-beef-85f354679565.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3632_SALIVA (Saliva), aliquot MBCProject_3632_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b1a3835-4007-4ed7-a712-d29615307bc4

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Frame Shift Del 3, Intron 3, Frame Shift Ins 3, 3'UTR 2, Nonsense Mutation 1, Translation Start Site 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.955dup p.T319Nfs*6 | Frame Shift Ins (INS) | VAF 43/124 reads (35%) | catalogued as rs786204892, CI075686, COSV64290023; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANKRD11 | c.7753C>T p.R2585C | Missense Mutation (SNP) | VAF 51/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567537304, COSV99968515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFRP1 | c.29_34del p.K10_Y11del | In Frame Del (DEL) | VAF 16/186 reads (9%) | catalogued as rs755724981; called by mutect2, pindel
- ARHGAP19 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138319737; called by muse, mutect2, varscan2
- ARHGAP21 | c.3643G>A p.D1215N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1564968953, COSV57601918; called by muse, mutect2, varscan2
- FNDC1 | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); catalogued as COSV51931781; called by muse, mutect2, varscan2
- GPR101 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV99981551; called by muse, mutect2, varscan2
- INTS5 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.51); catalogued as rs1158584239, COSV57950150; called by muse, mutect2, varscan2
- KCNU1 | c.2348C>T p.S783F | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV67754924; called by muse, mutect2, varscan2
- MATN2 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs758729757, COSV54720384; called by muse, varscan2
- NDUFAF5 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs367645690; called by muse, mutect2, varscan2
- OR5AK2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs200727671; called by muse, mutect2, varscan2
- RBFOX1 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60990469; called by muse, mutect2
- RIMS4 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV65719168; called by muse, mutect2, varscan2
- SLC1A3 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.111); catalogued as rs369119814, COSV54317412; called by mutect2, varscan2
- TENM2 | c.2692G>A p.A898T (on ENST00000518659 / NM_001122679.2; = p.A666T on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs755244663, COSV69122241; called by muse, mutect2, varscan2
- UNC13C | c.3329A>G p.Y1110C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.621); catalogued as rs773043990; called by muse, mutect2, varscan2
- AMPD2 | c.1596_1627del p.Q532Hfs*29 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by mutect2, pindel
- ANKS1B | c.2527G>T p.G843* (on ENST00000547776 / NM_152788.4; = p.G69* on NM_020140.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- BBOX1 | c.760T>A p.S254T | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLCN7 | c.1361G>T p.C454F | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CORO2B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- CYCS | c.199dup p.E67Gfs*21 | Frame Shift Ins (INS) | VAF 58/315 reads (18%) | called by mutect2, pindel, varscan2
- DNAAF6 | c.66C>G p.D22E | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- DYNC1H1 | c.12121G>A p.V4041I | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- EPHA1 | c.1840G>T p.D614Y | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- F8 | c.3409_3410del p.L1137Efs*28 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by pindel, varscan2
- H3-3B | c.344C>G p.A115G | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIK3R1 | c.1714_1721del p.Q572Kfs*27 (on ENST00000521381 / NM_181523.3; = p.Q302Kfs*27 on NM_181504.4) | Frame Shift Del (DEL) | VAF 17/121 reads (14%) | called by mutect2, pindel*
- POLR2A | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PTPN2 | c.528T>G p.H176Q | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- RBM18 | c.28dup p.L10Pfs*46 | Frame Shift Ins (INS) | VAF 14/138 reads (10%) | called by mutect2, pindel
- RSC1A1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SULT2B1 | c.320T>C p.I107T (on ENST00000201586 / NM_177973.2; = p.I92T on NM_004605.2) | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ALDH16A1 | c.1401C>T p.C467= | Silent (SNP) | VAF 42/157 reads (27%) | called by muse, mutect2, varscan2
- GAS7 | c.558G>A p.T186= (on ENST00000432992 / NM_201433.2; = p.T46= on NM_003644.3) | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs773453801; called by muse, mutect2, varscan2
- MPP2 | c.591G>A p.V197= (on ENST00000461854 / NM_001278372.2; = p.V173= on NM_005374.5) | Silent (SNP) | VAF 33/287 reads (11%) | called by muse, mutect2, varscan2
- POMC | c.12G>A p.S4= | Silent (SNP) | VAF 29/178 reads (16%) | catalogued as rs773178150, COSV53034532; called by muse, mutect2, varscan2
- RCC1 | c.129C>A p.G43= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1235632614, COSV65778936; called by muse, mutect2
- RNF213 | c.14067G>C p.L4689= | Silent (SNP) | VAF 24/195 reads (12%) | called by muse, mutect2, varscan2
- SEMG1 | c.870T>A p.S290= | Silent (SNP) | VAF 32/250 reads (13%) | called by muse, mutect2, varscan2
- SH3TC2 | c.1170T>C p.D390= | Silent (SNP) | VAF 48/317 reads (15%) | called by muse, mutect2, varscan2
- SIRPG | c.1086G>A p.P362= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs372945543; called by muse, mutect2, varscan2
- SLC4A10 | c.315C>T p.T105= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as rs374865086; called by muse, mutect2, varscan2
- WDR76 | c.1758G>A p.S586= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs752789943; called by muse, varscan2
- ARFGAP3 | chr22:42858434 G>A | 5'Flank (SNP) | VAF 11/116 reads (9%) | catalogued as rs1251867768; called by muse, mutect2
- KDM5B | c.577-23A>G | Intron (SNP) | VAF 37/226 reads (16%) | catalogued as rs1393042990; called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53336T>A | Intron (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- PHC3 | c.379-1405G>C | Intron (SNP) | VAF 8/76 reads (11%) | called by muse, varscan2
- TMEM135 | c.*7364A>C | 3'UTR (SNP) | VAF 7/107 reads (7%) | catalogued as rs1184459552; called by muse, mutect2
- UMPS | c.*1333T>G | 3'UTR (SNP) | VAF 5/51 reads (10%) | catalogued as rs1339329329; called by mutect2, varscan2
